TCGA case TCGA-01-0637 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Ovary; Tissue source site: International Genomics Consortium.
https://portal.gdc.cancer.gov/cases/124fd913-124b-44f5-8728-1591a0771e9b

Biospecimens (1 sample)
- Sample TCGA-01-0637-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.3.
